TCGA case TCGA-AZ-4684 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cac80259-3a26-4a99-b0d3-13454068e6ed

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 50.0 years (18,252 days); Year of diagnosis: 2006; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVA; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,977 days (5.4 years).
   Pathology details: Circumferential resection margin: 34; Consistent pathology review: Yes; Lymph nodes positive: 10; Lymph nodes tested: 12; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Regimen or line of therapy: FOLFOX; Days to treatment start: 22 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment start: 22 days.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Liver; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 51.1 years (18,663 days); Days to diagnosis: 411 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 411 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to recurrence: 411 days (1.1 years).
- Days to follow up: 1,705 days (4.7 years); Disease response: With Tumor.
- Days to follow up: 1,977 days (5.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 8.9 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 94 kg.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AZ-4684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-AZ-4684-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-AZ-4684-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 15; Percent stromal cells: 15.
- Sample TCGA-AZ-4684-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AZ-4684-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Colon; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 8.9; Lymphovascular invasion indicator: Yes.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,977 days; disease-specific survival: no event (censored), 1,977 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 411 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AZ-4684-01): tumor purity 0.47, ploidy 3.65, whole-genome doublings 1 (call status: legacy_call).
